Somatic mutation profile of tumor specimen MMRF_2750_1_BM_CD138pos (aliquot MMRF_2750_1_BM_CD138pos_T1_KHS5U_L14904) from MMRF case MMRF_2750, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 39.9 years (14,562 days).
Specimen MMRF_2750_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6f8ec38a-44f5-4889-91fa-01b0f29bef0c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2750_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2750_1_PB_WBC_C3_KHS5U_L14905; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0781465f-eb2d-4069-969b-770595033037

The open-access MAF lists 33 somatic variants for this specimen: 17 protein-altering or splice-affecting, 3 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, 3'UTR 4, Intron 4, Silent 3, 5'UTR 2, 3'Flank 2, Nonsense Mutation 1, 5'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID4B | c.1776T>G p.I592M | Missense Mutation (SNP) | VAF 83/209 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV51597660; called by muse, mutect2, varscan2
- IGHV1-69D | c.246G>C p.K82N | Missense Mutation (SNP) | VAF 50/108 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as rs1306711256; called by muse, varscan2
- IGHV1-69D | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.07); catalogued as rs1283966798; called by muse, varscan2
- IGLV3-1 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.138); catalogued as rs529856363; called by muse, varscan2
- IGLV3-1 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 71/187 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.397); catalogued as rs534336891; called by muse, varscan2
- OIT3 | c.1552C>T p.R518C | Missense Mutation (SNP) | VAF 54/135 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs191842788; called by muse, mutect2, varscan2
- PRRX1 | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 60/211 reads (28%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as rs755301434, COSV53410932; called by muse, mutect2, varscan2
- RYR2 | c.13198G>T p.A4400S | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.223); catalogued as rs750662333; called by muse, mutect2, varscan2
- ZNF235 | c.1165G>A p.D389N | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.77); PolyPhen probably damaging (0.967); catalogued as COSV52158554; called by muse, mutect2, varscan2
- ARID1B | c.339_374del p.F113_Q125delinsL | In Frame Del (DEL) | VAF 7/45 reads (16%) | called by mutect2, pindel
- CILK1 | c.801G>A p.W267* | Nonsense Mutation (SNP) | VAF 12/183 reads (7%) | called by muse, mutect2
- DSCAM | c.3751C>A p.L1251M | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PDZRN3 | c.1709G>A p.G570D | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- PIK3CD | c.2269A>G p.K757E | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- STK11IP | c.2135G>C p.S712T | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TPX2 | c.1511A>C p.E504A | Missense Mutation (SNP) | VAF 6/144 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.767); called by muse, mutect2
- WDR5 | c.287C>T p.S96L | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPM6A | c.615T>C p.T205= | Silent (SNP) | VAF 16/63 reads (25%) | called by muse, mutect2, varscan2
- PRR22 | c.57G>A p.P19= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as rs576243003; called by muse, mutect2, varscan2
- SALL3 | c.1155C>T p.N385= | Silent (SNP) | VAF 7/96 reads (7%) | catalogued as COSV73306295; called by muse, mutect2
- ADAMTSL1 | c.1342-380C>T | Intron (SNP) | VAF 4/43 reads (9%) | catalogued as rs1032992452; called by muse, mutect2
- CCDC184 | c.-465T>A | 5'UTR (SNP) | VAF 19/72 reads (26%) | called by muse, mutect2, varscan2
- CDH8 | c.*855A>C | 3'UTR (SNP) | VAF 16/54 reads (30%) | called by muse, varscan2
- HCN4 | c.*2196G>A | 3'UTR (SNP) | VAF 17/158 reads (11%) | catalogued as rs560818486; called by muse, mutect2, varscan2
- HDAC7 | c.2590-106C>G | Intron (SNP) | VAF 10/44 reads (23%) | called by muse, mutect2
- HEMK1 | c.-36A>C | 5'UTR (SNP) | VAF 21/83 reads (25%) | called by muse, mutect2, varscan2
- HOXB3 | chr17:48545716 G>T | 3'Flank (SNP) | VAF 43/148 reads (29%) | called by muse, mutect2, varscan2
- INHBA | c.*1462A>T | 3'UTR (SNP) | VAF 17/76 reads (22%) | called by muse, mutect2, varscan2
- MTO1 | chr6:73461686 A>C | 5'Flank (SNP) | VAF 18/44 reads (41%) | catalogued as rs947659374; called by muse, mutect2, varscan2
- PLOD2 | c.880-89T>G | Intron (SNP) | VAF 17/49 reads (35%) | called by muse, mutect2
- RBFOX1 | chr16:7711372 T>C | 3'Flank (SNP) | VAF 5/112 reads (4%) | catalogued as rs931168956; called by muse, mutect2
- SFTA3 | n.937+21G>A | Intron (SNP) | VAF 35/103 reads (34%) | catalogued as rs747776643; called by muse, mutect2, varscan2
- SPEN | c.*353T>C | 3'UTR (SNP) | VAF 30/83 reads (36%) | called by muse, mutect2, varscan2
